Somatic mutation profile of tumor specimen ALCH-ADXK-TTP1-A (aliquot ALCH-ADXK-TTP1-A-1-0-D-A603-36) from ALCHEMIST case ALCH-ADXK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.8 years (21,128 days).
Specimen ALCH-ADXK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4047b6e-0efa-48d2-9e94-be4b3ba1750f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADXK-NB1-A (Blood Derived Normal), aliquot ALCH-ADXK-NB1-A-1-0-D-A603-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddaadd5d-05bc-44dc-ba89-7191e0bda184

The open-access MAF lists 1,348 somatic variants for this specimen: 942 protein-altering or splice-affecting, 258 silent, 148 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 815, Silent 258, Intron 64, Nonsense Mutation 57, Splice Site 29, RNA 28, 5'UTR 22, Frame Shift Del 19, 3'UTR 15, Splice Region 14, 3'Flank 11, 5'Flank 8.

Variants (750 of 1,348; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 137/648 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>C p.R337P | Missense Mutation (SNP) | VAF 67/345 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.9424G>T p.G3142* | Nonsense Mutation (SNP) | VAF 40/492 reads (8%) | catalogued as rs397518048, CM073413, COSV100237450, COSV56335394; ClinVar: pathogenic; called by muse, mutect2
- ACSS3 | c.1928C>A p.P643H | Missense Mutation (SNP) | VAF 112/603 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54089239; called by muse, mutect2, varscan2
- ADAM28 | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 95/477 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as COSV56099872; called by muse, mutect2, varscan2
- ADAMTS12 | c.3625T>C p.W1209R | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs761144578; called by muse, mutect2, varscan2
- ADAMTS3 | c.1005G>T p.W335C | Missense Mutation (SNP) | VAF 110/479 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99078496; called by muse, mutect2, varscan2
- ADCY2 | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 52/388 reads (13%) | catalogued as COSV99059536; called by muse, mutect2
- ADCY8 | c.2521G>T p.V841L | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs1554605126; called by muse, mutect2
- ADORA1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.747); catalogued as rs778641521, COSV55142136, COSV99704669; called by muse, mutect2, varscan2
- ADRB3 | c.949C>A p.L317M | Missense Mutation (SNP) | VAF 76/480 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as rs199797640; called by muse, mutect2, varscan2
- AIFM3 | c.662G>C p.R221P | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58999900; called by muse, mutect2
- ANGPTL7 | c.401T>C p.L134P | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472194287; called by muse, mutect2, varscan2
- ARHGAP21 | c.2848-1G>T p.X950_splice | Splice Site (SNP) | VAF 46/235 reads (20%) | catalogued as COSV57606418; called by muse, mutect2, varscan2
- ARHGAP36 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV52271114; called by muse, mutect2, varscan2
- ARHGEF25 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 92/384 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.809); catalogued as rs201573584; called by muse, mutect2, varscan2
- ATP6V1H | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62217609; called by muse, mutect2, varscan2
- BTNL9 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 109/557 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs373558505; called by muse, mutect2, varscan2
- C1orf185 | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1460618659; called by muse, mutect2, varscan2
- CACNA1B | c.5507C>T p.T1836I | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV53113922; called by muse, mutect2, varscan2
- CACTIN | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50271057; called by muse, mutect2, varscan2
- CAD | c.1842G>T p.T614= | Splice Region (SNP) | VAF 78/305 reads (26%) | catalogued as rs778481242; called by muse, mutect2, varscan2
- CANT1 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 129/773 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as rs375322541; called by muse, mutect2, varscan2
- CASP8AP2 | c.4178G>T p.G1393V | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV52745161; called by muse, mutect2, varscan2
- CAT | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 72/694 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768277375; called by muse, varscan2
- CCDC169 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.178); catalogued as COSV53488027; called by muse, mutect2, varscan2
- CCDC198 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as rs112954258, COSV53602909; called by muse, mutect2, varscan2
- CCDC30 | c.1542G>T p.E514D (on ENST00000340612; = p.E471D on NM_001080850.3) | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV104412008; called by muse, mutect2, varscan2
- CCND2 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.038); catalogued as COSV54224916; called by muse, mutect2, varscan2
- CD163 | c.3089-1G>T p.X1030_splice | Splice Site (SNP) | VAF 19/166 reads (11%) | catalogued as COSV63132918, COSV63138990; called by muse, mutect2, varscan2
- CFAP77 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 87/507 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.081); catalogued as COSV100546090; called by muse, mutect2, varscan2
- CFLAR | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs371340033; called by muse, mutect2
- CHRNA4 | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 219/923 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV64719561; called by muse, mutect2, varscan2
- CLCN1 | c.720C>A p.S240R | Missense Mutation (SNP) | VAF 65/464 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs764402957; called by muse, mutect2, varscan2
- CLEC2L | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101406086, COSV70691057; called by muse, mutect2, varscan2
- CLVS2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 190/765 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as rs752596301, COSV51558951; called by muse, mutect2, varscan2
- CNGB3 | c.1806C>G p.N602K | Missense Mutation (SNP) | VAF 91/1001 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769171325; called by muse, mutect2
- CNTNAP2 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 131/583 reads (22%) | catalogued as COSV100665155, COSV62143236; called by muse, mutect2, varscan2
- COL4A2 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs1017730027; called by muse, mutect2, varscan2
- CORO1B | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs752869875; called by muse, mutect2, varscan2
- CSF3R | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV58966999; called by muse, mutect2, varscan2
- CSMD1 | c.2098G>T p.D700Y (on ENST00000520002; = p.D699Y on NM_033225.6) | Missense Mutation (SNP) | VAF 58/451 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100146706; called by muse, mutect2, varscan2
- CSMD2 | c.10164G>A p.L3388= | Splice Region (SNP) | VAF 47/361 reads (13%) | catalogued as rs1329526532; called by muse, mutect2, varscan2
- CSMD3 | c.9686G>C p.R3229T (on ENST00000297405 / NM_001363185.1; = p.R3060T on NM_052900.3) | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52184322; called by muse, mutect2, varscan2
- CSNK2A3 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 108/865 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57158863, COSV99074314, COSV99923935; called by muse, mutect2, varscan2
- CYB5R1 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100924852; called by muse, mutect2, varscan2
- CYP11B2 | c.1354G>T p.G452W | Missense Mutation (SNP) | VAF 70/416 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59998253; called by muse, varscan2
- DACH2 | c.1615C>A p.R539S | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100913098; called by muse, mutect2, varscan2
- DDI1 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs1330324603; called by muse, mutect2
- DDX60L | c.3269T>C p.M1090T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1360172543; called by muse, mutect2, varscan2
- DLG2 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 78/898 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54677661; called by muse, mutect2
- DMBT1 | c.3178G>A p.V1060M (on ENST00000338354 / NM_001377530.1; = p.V561M on NM_004406.3) | Missense Mutation (SNP) | VAF 53/1184 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs749361568; called by muse, mutect2
- DMD | c.6494C>A p.T2165N | Missense Mutation (SNP) | VAF 126/425 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs768712703; called by muse, mutect2, varscan2
- DMXL1 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 123/413 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs375308972; called by muse, mutect2, varscan2
- DNAH10 | c.9560C>T p.T3187M (on ENST00000409039; = p.T3126M on NM_207437.3) | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs750866999; called by muse, mutect2, varscan2
- DNAH17 | c.4960G>A p.E1654K | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs1323894685; called by muse, mutect2, varscan2
- DSCAM | c.5623C>G p.P1875A | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68035995; called by muse, mutect2, varscan2
- DSG2 | c.46-1G>C p.X16_splice | Splice Site (SNP) | VAF 67/263 reads (25%) | catalogued as COSV55198191, COSV55200337; called by muse, mutect2, varscan2
- DSG3 | c.1149C>G p.F383L | Missense Mutation (SNP) | VAF 113/425 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99934145; called by muse, varscan2
- ECEL1 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100458549; called by muse, mutect2, varscan2
- ELAVL2 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99805370; called by muse, mutect2
- EMCN | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 91/408 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs775315481; called by muse, mutect2, varscan2
- EML6 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755547829; called by muse, mutect2, varscan2
- EML6 | c.4258C>A p.L1420I | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62866487; called by muse, mutect2, varscan2
- ENKUR | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482289; called by muse, mutect2, varscan2
- ETV1 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 35/473 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54143241; called by muse, mutect2
- F2R | c.512G>C p.G171A | Missense Mutation (SNP) | VAF 281/923 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59928844; called by muse, mutect2, varscan2
- FAM184B | c.2085C>G p.I695M | Missense Mutation (SNP) | VAF 84/415 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1371053861; called by muse, mutect2, varscan2
- FAM47C | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 119/442 reads (27%) | catalogued as COSV63730989; called by muse, mutect2, varscan2
- FBXL7 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 182/799 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV61647265; called by muse, mutect2, varscan2
- FCRLA | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.003); catalogued as COSV99376376; called by muse, mutect2, varscan2
- FEZ1 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 56/618 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV54032214; called by muse, mutect2
- FJX1 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.399); catalogued as rs757323111; called by muse, mutect2, varscan2
- FLG | c.5630G>C p.G1877A | Missense Mutation (SNP) | VAF 97/955 reads (10%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as COSV100910908; called by muse, mutect2, varscan2
- FLG2 | c.3572G>C p.S1191T | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV66172399; called by muse, varscan2
- FLRT2 | c.1681G>T p.V561F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs866997043, COSV58149334; called by muse, mutect2, varscan2
- FLRT2 | c.1894G>T p.G632W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58152689; called by muse, mutect2, varscan2
- FMN2 | c.3496C>A p.P1166T | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV60431269; called by muse, varscan2
- FUT9 | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV56148029; called by muse, mutect2, varscan2
- GABRA2 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 105/570 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.338); catalogued as COSV100733796; called by muse, mutect2, varscan2
- GABRB1 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 79/480 reads (16%) | catalogued as COSV54981483, COSV99782313; called by muse, varscan2
- GATA3 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 240/1096 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1111242, COSV99062031; called by muse, mutect2, varscan2
- GATB | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs1400137209, COSV56130487; called by muse, mutect2, varscan2
- GGA2 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59168150; called by muse, mutect2, varscan2
- GIGYF2 | c.722G>C p.R241P | Missense Mutation (SNP) | VAF 145/1031 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV65250342; called by muse, mutect2, varscan2
- GINS1 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 122/574 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV52467109; called by muse, varscan2
- GJB4 | c.220G>C p.V74L | Missense Mutation (SNP) | VAF 157/520 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as CM073101; called by muse, mutect2, varscan2
- GLUL | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 231/1156 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as rs1490403967, COSV59382020, COSV59382101; called by muse, mutect2, varscan2
- GMIP | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1220823788; called by muse, mutect2, varscan2
- GNAT3 | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68068722; called by muse, mutect2, varscan2
- GOLGA3 | c.1407G>T p.E469D | Missense Mutation (SNP) | VAF 79/597 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.51); catalogued as COSV52644368; called by muse, mutect2, varscan2
- GPR22 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51761214; called by muse, mutect2, varscan2
- GPR26 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV52933248; called by muse, mutect2
- GRIK2 | c.1654G>T p.V552F | Missense Mutation (SNP) | VAF 150/659 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as rs780955412, COSV59712607; called by muse, mutect2, varscan2
- GRIN3A | c.36G>T p.R12S | Missense Mutation (SNP) | VAF 496/1141 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.715); catalogued as rs969833256; called by muse, mutect2, varscan2
- HEATR4 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV58578196; called by muse, mutect2, varscan2
- HECW1 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV67826842; called by mutect2, varscan2
- HOXC9 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57716551; called by muse, mutect2, varscan2
- HR | c.826T>C p.W276R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs944387514; called by muse, mutect2, varscan2
- IDUA | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1374359136, CM146929; called by mutect2, varscan2
- IGHG2 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 68/778 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765439103; called by muse, mutect2
- IGKV2D-26 | c.97A>T p.I33F | Missense Mutation (SNP) | VAF 52/496 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs768027277; called by muse, mutect2, varscan2
- IGLV5-37 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 81/466 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs746268408; called by muse, mutect2, varscan2
- IGSF9B | c.961G>T p.V321L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100317872; called by muse, mutect2, varscan2
- INTS7 | c.1871G>T p.R624M | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65343719; called by muse, mutect2, varscan2
- IQSEC3 | c.3325C>G p.R1109G | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs1461707658; called by muse, mutect2, varscan2
- IRS2 | c.2494C>G p.R832G | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV65478579; called by muse, mutect2, varscan2
- IRX1 | c.1368C>A p.F456L | Missense Mutation (SNP) | VAF 41/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs924645279; called by muse, mutect2
- ITGA1 | c.2695-1G>A p.X899_splice | Splice Site (SNP) | VAF 5/54 reads (9%) | catalogued as rs1361447685, COSV99251452; called by muse, mutect2, varscan2
- ITGAD | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66756806; called by muse, mutect2, varscan2
- ITLN1 | c.382del p.A128Rfs*40 | Frame Shift Del (DEL) | VAF 130/667 reads (19%) | catalogued as COSV100406268; called by mutect2, pindel, varscan2
- KBTBD4 | c.1243T>G p.Y415D | Missense Mutation (SNP) | VAF 86/782 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs1001981342; called by muse, mutect2, varscan2
- KIF17 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 109/425 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.169); catalogued as rs146714930; called by muse, mutect2, varscan2
- KLHL6 | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 194/1014 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV58069562; called by muse, mutect2, varscan2
- KLK14 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50072357; called by muse, mutect2, varscan2
- KRT6A | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 281/894 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as rs180935064; called by muse, mutect2, varscan2
- KRT9 | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs772792541; called by muse, mutect2, varscan2
- KRTAP5-8 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 63/580 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.025); catalogued as rs1260736116; called by muse, mutect2, varscan2
- KYNU | c.290+1G>T p.X97_splice | Splice Site (SNP) | VAF 16/137 reads (12%) | catalogued as rs751576959; called by muse, mutect2, varscan2
- LCT | c.4759C>A p.R1587S | Missense Mutation (SNP) | VAF 143/641 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51548620; called by muse, mutect2, varscan2
- LIX1 | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 129/615 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57206981; called by muse, varscan2
- LMTK2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 445/681 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762097175; called by muse, mutect2, varscan2
- LPGAT1 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 53/654 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65351256; called by muse, mutect2
- LRP1B | c.1342C>A p.H448N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs1024479933, COSV67203637; called by muse, mutect2, varscan2
- LRRC6 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs139065705; called by muse, mutect2
- LRRC66 | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 50/455 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.39); catalogued as COSV100602922; called by muse, mutect2, varscan2
- LRRCC1 | c.1316G>T p.R439I | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100835534, COSV64484182; called by muse, mutect2
- LTBP4 | c.4546C>T p.P1516S (on ENST00000308370 / NM_001042544.1; = p.P1479S on NM_003573.2) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1015881478; called by muse, varscan2
- LYNX1-SLURP2 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58186555; called by muse, mutect2, varscan2
- MAEL | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV63306354; called by muse, mutect2, varscan2
- MAGEA3 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 80/240 reads (33%) | catalogued as COSV64756493; called by muse, mutect2, varscan2
- MANEA | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 74/285 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as rs761177302; called by muse, varscan2
- MAP3K7 | c.1430G>A p.R477Q (on ENST00000369329 / NM_145331.3; = p.R450Q on NM_003188.4) | Missense Mutation (SNP) | VAF 80/388 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs183005565; called by muse, mutect2, varscan2
- MAP3K7CL | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.88); catalogued as rs752198255, COSV54510630; called by muse, mutect2, varscan2
- MBD5 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 121/790 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1411318062; called by muse, mutect2, varscan2
- MCCC1 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 341/1845 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs1490366527; called by muse, mutect2, varscan2
- MERTK | c.2197G>C p.D733H | Missense Mutation (SNP) | VAF 106/892 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201840939, COSV54929913; called by muse, mutect2, varscan2
- MLLT10 | c.1544G>T p.S515I | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV57006303; called by muse, mutect2, varscan2
- MROH2B | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs1230762999; called by muse, mutect2, varscan2
- MS4A14 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 112/478 reads (23%) | catalogued as COSV100280287; called by muse, mutect2, varscan2
- MTHFSD | c.16+3G>T | Splice Region (SNP) | VAF 43/147 reads (29%) | catalogued as rs577129060; called by muse, mutect2, varscan2
- MTMR7 | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs139002520; called by muse, mutect2, varscan2
- MTR | c.1915G>C p.D639H | Missense Mutation (SNP) | VAF 285/1228 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV63965585; called by muse, mutect2, varscan2
- MUC16 | c.30616T>C p.S10206P | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.326); catalogued as COSV67477644; called by muse, mutect2
- MUC16 | c.30614C>A p.S10205Y | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs747376659, COSV67456351; called by muse, mutect2
- MUC16 | c.13627G>A p.G4543R | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as rs1355359113; called by muse, mutect2, varscan2
- MUC17 | c.6706G>T p.E2236* | Nonsense Mutation (SNP) | VAF 44/431 reads (10%) | catalogued as COSV60284165; called by muse, mutect2, varscan2
- MUC17 | c.12985G>A p.V4329I | Missense Mutation (SNP) | VAF 80/456 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs149074951; called by muse, mutect2, varscan2
- MUC19 | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 64/514 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as rs1214601953; called by muse, mutect2, varscan2
- MYH2 | c.3025C>A p.H1009N | Missense Mutation (SNP) | VAF 205/1490 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV55431934; called by muse, mutect2, varscan2
- MYH4 | c.4618G>T p.E1540* | Nonsense Mutation (SNP) | VAF 61/241 reads (25%) | catalogued as COSV99700988; called by muse, mutect2, varscan2
- MYH8 | c.4111G>T p.V1371F | Missense Mutation (SNP) | VAF 139/947 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67965186; called by muse, mutect2, varscan2
- MYH8 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 176/761 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV67970825; called by muse, mutect2, varscan2
- MYO15A | c.9894G>T p.W3298C | Missense Mutation (SNP) | VAF 95/783 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52761325; called by muse, mutect2, varscan2
- MYO7A | c.6410G>T p.G2137V | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM971018; called by muse, mutect2, varscan2
- NAP1L2 | c.617A>G p.Y206C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs756320901; called by muse, varscan2
- NAV3 | c.5591G>C p.R1864P (on ENST00000397909 / NM_001024383.2; = p.R1842P on NM_014903.6) | Missense Mutation (SNP) | VAF 87/862 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57083190, COSV99895292; called by muse, mutect2, varscan2
- NCKAP1L | c.213G>T p.T71= | Splice Region (SNP) | VAF 35/163 reads (21%) | catalogued as COSV53203896; called by muse, mutect2, varscan2
- NEB | c.8730G>C p.W2910C | Missense Mutation (SNP) | VAF 82/612 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448224160, COSV50819273; called by muse, mutect2, varscan2
- NEU4 | c.616G>T p.G206C (on ENST00000391969 / NM_001167602.3; = p.G218C on NM_080741.4) | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488157571, COSV100371857, COSV57992607; called by muse, mutect2, varscan2
- NIBAN3 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs747029118; called by muse, mutect2, varscan2
- NLRC4 | c.1918C>A p.P640T | Missense Mutation (SNP) | VAF 47/331 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61592203; called by muse, mutect2, varscan2
- NME8 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 126/604 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs776436705; called by muse, mutect2, varscan2
- NOS1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs529671468, COSV57607848; called by muse, mutect2, varscan2
- NOX1 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54196004; called by muse, varscan2
- NPAP1 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61506776, COSV61510815; called by muse, mutect2
- NPAS4 | c.1400C>A p.S467Y | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100215151; called by muse, mutect2, varscan2
- NPC1L1 | c.3640C>G p.R1214G | Missense Mutation (SNP) | VAF 66/576 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56926001; called by muse, mutect2, varscan2
- NRDC | c.631-1G>C p.X211_splice | Splice Site (SNP) | VAF 38/168 reads (23%) | catalogued as COSV61404567; called by muse, mutect2, varscan2
- NSD1 | c.6320G>A p.R2107H | Missense Mutation (SNP) | VAF 233/1048 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1401142770, COSV100729097; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP210 | c.4788G>T p.Q1596H | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV99597041; called by muse, mutect2, varscan2
- OR14I1 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 157/628 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV100700492, COSV61200709; called by muse, mutect2, varscan2
- OR2L8 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 131/663 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs528613536, COSV100594200, COSV61726384; called by muse, mutect2, varscan2
- OR2T6 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs758224437, COSV63216283; called by muse, varscan2
- OR2T6 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.984); catalogued as COSV63215996; called by muse, mutect2, varscan2
- OR4A47 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs779471956; called by muse, mutect2, varscan2
- OR4D6 | c.214G>T p.V72F | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1250205000, COSV55660371; called by muse, mutect2, varscan2
- OR4D9 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 115/412 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs770967900; called by muse, mutect2, varscan2
- OR6T1 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 24/716 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100190207; called by muse, mutect2
- OR6Y1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 98/557 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.328); catalogued as COSV56931645; called by muse, mutect2, varscan2
- OR8H3 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV57909005; called by muse, varscan2
- P2RY4 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65736210; called by muse, mutect2, varscan2
- PADI1 | c.573C>A p.D191E | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs762187386; called by muse, mutect2, varscan2
- PANX2 | c.1775G>T p.R592L | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV99348060; called by muse, mutect2, varscan2
- PCARE | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 197/1310 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1026914983; called by muse, mutect2, varscan2
- PCDHA6 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 300/1382 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as rs782489134, COSV65352609; called by muse, varscan2
- PCDHB10 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 328/1102 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs1358381709, COSV53381710; called by muse, mutect2, varscan2
- PCDHB9 | c.1893C>A p.S631R | Missense Mutation (SNP) | VAF 310/1080 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1233413065; called by muse, mutect2, varscan2
- PCDHGA1 | c.1990G>T p.V664L | Missense Mutation (SNP) | VAF 153/593 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.273); catalogued as COSV65296000; called by muse, mutect2, varscan2
- PCLO | c.7834G>T p.D2612Y | Missense Mutation (SNP) | VAF 99/425 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs912860603, COSV61617460, COSV61652707; called by muse, mutect2, varscan2
- PGLYRP4 | c.472+1G>T p.X158_splice | Splice Site (SNP) | VAF 43/202 reads (21%) | catalogued as COSV62836077; called by muse, mutect2, varscan2
- PHGR1 | c.175del p.H59Tfs*49 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | catalogued as rs748850271; called by pindel, varscan2
- PIGU | c.428+1G>T p.X143_splice | Splice Site (SNP) | VAF 97/497 reads (20%) | catalogued as rs1471915359; called by muse, mutect2, varscan2
- PKD1 | c.6227C>T p.S2076L | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as rs758919000; called by muse, mutect2, varscan2
- PLCB2 | c.1984C>A p.R662S | Missense Mutation (SNP) | VAF 69/462 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773166806, COSV53038519; called by muse, mutect2, varscan2
- PLCL1 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 135/679 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559099836, COSV70821454, COSV70821834; called by muse, mutect2, varscan2
- PLPPR4 | c.1065C>A p.N355K | Missense Mutation (SNP) | VAF 56/670 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.021); catalogued as COSV64565394; called by muse, mutect2
- PPIP5K1 | c.3248-1G>T p.X1083_splice (on ENST00000396923; = p.X1058_splice on NM_014659.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 31/196 reads (16%) | catalogued as COSV100613188; called by muse, mutect2
- PPP2R3B | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.554); catalogued as rs201641619; called by muse, mutect2, varscan2
- PPP4R3C | c.1342C>A p.R448S | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV69080797; called by muse, mutect2, varscan2
- PRDM9 | c.1749G>C p.R583S | Missense Mutation (SNP) | VAF 198/1003 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as COSV57009325; called by muse, mutect2, varscan2
- PSPC1 | c.771-1G>T p.X257_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99071097; called by muse, mutect2
- PTGER3 | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 90/408 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.775); catalogued as rs1385948968; called by muse, varscan2
- PTGER3 | c.1098C>A p.N366K | Missense Mutation (SNP) | VAF 54/415 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60699571; called by muse, varscan2
- PTGER3 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 66/679 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60695704; called by muse, mutect2
- PTGER3 | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 69/571 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100138763; called by muse, mutect2, varscan2
- PTGS1 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV99793105, COSV99793318; called by muse, varscan2
- PTPRD | c.569-7C>A | Splice Region (SNP) | VAF 173/581 reads (30%) | catalogued as COSV61934657; called by muse, mutect2, varscan2
- PTPRT | c.2552G>T p.R851L | Missense Mutation (SNP) | VAF 85/311 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.388); catalogued as rs372056802, COSV61993574; called by muse, mutect2, varscan2
- PXDNL | c.2294G>T p.R765L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.804); catalogued as COSV100685952; called by muse, mutect2, varscan2
- RAC1 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 49/445 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61822114, COSV61824812; called by muse, mutect2, varscan2
- RBFOX1 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60946461, COSV60979056; called by muse, mutect2, varscan2
- RBP4 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 204/700 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as COSV65160703; called by muse, mutect2, varscan2
- RIT2 | c.62A>T p.Y21F | Missense Mutation (SNP) | VAF 109/432 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99949798; called by muse, mutect2, varscan2
- RSPO1 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 142/559 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs371551242; called by muse, mutect2, varscan2
- RUNX3 | c.1196C>A p.T399K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV58242842; called by muse, mutect2
- RYR2 | c.7375G>T p.G2459W | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV63722412; called by muse, mutect2, varscan2
- SALL3 | c.1075C>G p.P359A | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as rs781640431; called by muse, mutect2, varscan2
- SAMD9 | c.2812T>C p.C938R | Missense Mutation (SNP) | VAF 562/954 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180925271, COSV101180287; called by muse, mutect2, varscan2
- SCG2 | c.1068G>T p.R356S | Missense Mutation (SNP) | VAF 64/419 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.871); catalogued as rs376863178, COSV100544982, COSV59541555; called by muse, mutect2, varscan2
- SCN3A | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 194/981 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.068); catalogued as rs1212441241; called by muse, mutect2, varscan2
- SENP7 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 93/548 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs766150711, COSV58610547; called by muse, mutect2, varscan2
- SH2D4B | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1193089156; called by muse, mutect2, varscan2
- SIGLEC1 | c.609C>A p.H203Q | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.974); catalogued as rs1461404748; called by muse, varscan2
- SKOR2 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 185/580 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101247396; called by muse, mutect2, varscan2
- SLC17A6 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54136064; called by muse, mutect2
- SLC35C2 | c.413_414del p.A138Gfs*53 | Frame Shift Del (DEL) | VAF 28/181 reads (15%) | catalogued as rs1568714411; called by pindel, varscan2
- SLC6A5 | c.2167G>T p.A723S | Missense Mutation (SNP) | VAF 116/1091 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV54231213; called by muse, mutect2, varscan2
- SLITRK2 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100158290, COSV59423958; called by muse, mutect2, varscan2
- SNAP47 | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 95/487 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV59919867; called by muse, mutect2, varscan2
- SPEM2 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV61603194; called by muse, mutect2, varscan2
- SPTLC1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as rs527406013, COSV99364962; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRGAP2C | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 117/571 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs782100804, COSV100444046; called by muse, mutect2, varscan2
- ST18 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs766226164, COSV99389038; called by muse, mutect2, varscan2
- ST18 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 94/823 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1359736333; called by muse, mutect2, varscan2
- STAT1 | c.1399G>C p.G467R | Missense Mutation (SNP) | VAF 174/1230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100738513; called by muse, mutect2, varscan2
- STIL | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1557738904; called by muse, mutect2
- STOML3 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 91/540 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1190634522; called by muse, mutect2, varscan2
- STYXL2 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 24/955 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV54801619; called by muse, mutect2
- SUPT6H | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 63/609 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as rs1284185559, COSV58925542; called by muse, mutect2, varscan2
- SYNE1 | c.470G>A p.S157N (on ENST00000367255 / NM_182961.4; = p.S164N on NM_033071.3) | Missense Mutation (SNP) | VAF 266/951 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs763015621; called by muse, mutect2, varscan2
- SYNE2 | c.4855G>A p.E1619K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779215485; called by muse, mutect2, varscan2
- SYT16 | c.1556C>A p.T519K | Missense Mutation (SNP) | VAF 148/602 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70856141; called by muse, mutect2, varscan2
- TAS1R2 | c.2032C>A p.P678T | Missense Mutation (SNP) | VAF 118/1013 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV100946163; called by muse, mutect2, varscan2
- TAS2R16 | c.522T>A p.H174Q | Missense Mutation (SNP) | VAF 62/431 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs753550840; called by muse, mutect2, varscan2
- TBX15 | c.1667A>T p.Q556L (on ENST00000369429 / NM_001330677.2; = p.Q450L on NM_152380.3) | Missense Mutation (SNP) | VAF 57/483 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.989); catalogued as rs1232348960; called by muse, mutect2, varscan2
- TCF21 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 74/569 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs756756327, COSV52818753; called by muse, mutect2, varscan2
- TDGF1 | c.89-1G>T p.X30_splice | Splice Site (SNP) | VAF 245/798 reads (31%) | catalogued as COSV56129458; called by muse, mutect2, varscan2
- TECTA | c.4343G>T p.R1448L | Missense Mutation (SNP) | VAF 155/628 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866028341; called by muse, mutect2, varscan2
- TENM4 | c.7267G>A p.V2423M | Missense Mutation (SNP) | VAF 69/605 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759903805, COSV99579006; called by muse, mutect2, varscan2
- TENM4 | c.3244C>A p.P1082T | Missense Mutation (SNP) | VAF 72/498 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV53670909; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 84/1126 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV51512643; called by muse, mutect2
- THSD1 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 99/518 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as COSV99319066, COSV99319152; called by muse, mutect2, varscan2
- TNFAIP6 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 104/499 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.251); catalogued as COSV99693827; called by muse, mutect2, varscan2
- TNP1 | c.12C>A p.S4R | Missense Mutation (SNP) | VAF 145/602 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.452); catalogued as rs931941535; called by muse, mutect2, varscan2
- TOPBP1 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199552139; called by muse, mutect2, varscan2
- TRPA1 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 157/977 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759726700, COSV51571543; called by muse, mutect2, varscan2
- TRPS1 | c.3676G>A p.D1226N (on ENST00000220888 / NM_001330599.2; = p.D1239N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/964 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99629844; called by muse, mutect2, varscan2
- TTC5 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 126/559 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51871624; called by muse, mutect2, varscan2
- TTI1 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 122/522 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs763470567; called by muse, mutect2, varscan2
- TTN | c.40429C>A p.L13477M (on ENST00000591111; = p.L6053M on NM_003319.4) | Missense Mutation (SNP) | VAF 81/384 reads (21%) | PolyPhen possibly damaging (0.64); catalogued as COSV60145962; called by muse, mutect2, varscan2
- TTN | c.22986T>A p.S7662= (on ENST00000591111; = p.S6735= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 23/112 reads (21%) | catalogued as COSV60018641; called by muse, mutect2, varscan2
- TUBB1 | c.796T>C p.F266L | Missense Mutation (SNP) | VAF 93/446 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.433); catalogued as rs760261214; called by muse, mutect2, varscan2
- UBQLNL | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs557573869; called by muse, mutect2, varscan2
- UBR4 | c.6919G>T p.D2307Y | Missense Mutation (SNP) | VAF 56/516 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1332605600, COSV100920667; called by muse, mutect2, varscan2
- UGGT1 | c.2805G>T p.Q935H | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as COSV99391192; called by muse, mutect2, varscan2
- UHRF1BP1L | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs780255444; called by muse, varscan2
- UNC45B | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV52098287; called by muse, mutect2, varscan2
- VCAN | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 268/991 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV54107272; called by muse, mutect2, varscan2
- VPS13A | c.8235A>G p.I2745M | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as rs1440324757; called by muse, mutect2, varscan2
- VPS54 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 78/545 reads (14%) | catalogued as COSV55443523; called by muse, mutect2, varscan2
- WDR64 | c.1871C>A p.P624Q | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100844156; called by muse, mutect2, varscan2
- WDR97 | c.3106-8A>G | Splice Region (SNP) | VAF 56/187 reads (30%) | catalogued as rs980929966; called by muse, mutect2, varscan2
- WNT7A | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs1411629875, COSV53199784; called by muse, mutect2
- XIRP2 | c.833C>A p.P278H (on ENST00000628543; = p.P453H on NM_152381.6) | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99039676; called by muse, mutect2, varscan2
- YLPM1 | c.5455G>T p.V1819L | Missense Mutation (SNP) | VAF 126/555 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV53119506; called by muse, mutect2, varscan2
- ZBED9 | c.569-2A>G p.X190_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV71729803; called by muse, mutect2
- ZFHX3 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.199); catalogued as rs757081224, COSV51708575; called by muse, mutect2, varscan2
- ZFP57 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs769259227; called by muse, mutect2, varscan2
- ZMAT4 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs144919411, COSV52701716, COSV52713141; called by muse, mutect2
- ZNF207 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58300941; called by muse, mutect2
- ZNF208 | c.2858C>A p.A953D | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68104509; called by muse, mutect2, varscan2
- ZNF280B | c.18G>C p.E6D | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs761397877, COSV64529337; called by muse, mutect2, varscan2
- ZNF716 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV70779039; called by muse, mutect2, varscan2
- ZNF729 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.718); catalogued as rs1398242230; called by muse, mutect2, varscan2
- ZNF782 | c.451A>T p.M151L | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56654561; called by muse, mutect2, varscan2
- ZNF831 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as rs761317651, COSV64044285; called by muse, mutect2, varscan2
- ZP4 | c.481C>G p.R161G | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs192960963; called by muse, mutect2, varscan2
- AADACL3 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AADAT | c.607C>G p.P203A | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AASDH | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 119/555 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ABCC12 | c.1699T>A p.Y567N | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ABCC9 | c.478T>A p.L160M | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABLIM2 | c.1623G>T p.W541C (on ENST00000341937 / NM_001130084.2; = p.W575C on NM_001130083.2) | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- AC090517.4 | c.800G>C p.S267T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2
- AC126283.2 | c.1010G>T p.R337M | Missense Mutation (SNP) | VAF 172/663 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACADS | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2
- ACAN | c.4673C>A p.S1558Y | Missense Mutation (SNP) | VAF 127/629 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ACOD1 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACOT11 | c.384G>C p.Q128H | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ACOT4 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACSM1 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 195/734 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTRT2 | c.281T>A p.F94Y | Missense Mutation (SNP) | VAF 51/387 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACTRT3 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ADAD1 | c.963_976del p.I322Efs*5 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, varscan2
- ADAMTS12 | c.3626G>T p.W1209L | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS20 | c.2371G>A p.G791R | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS7 | c.4523C>A p.A1508D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.88); called by muse, varscan2
- ADAMTSL5 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- ADCY2 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 102/550 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY4 | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ADGRV1 | c.3851G>C p.G1284A | Missense Mutation (SNP) | VAF 275/1277 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- AFAP1 | c.2001G>T p.Q667H | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- AGAP1 | c.1522A>G p.I508V (on ENST00000304032 / NM_001037131.3; = p.I455V on NM_014914.5) | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- AGO2 | c.1215G>T p.M405I | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- AGTR2 | c.188T>G p.I63S | Missense Mutation (SNP) | VAF 75/328 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGXT2 | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 59/467 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AJAP1 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, varscan2
- AKAP6 | c.2692G>T p.V898L | Missense Mutation (SNP) | VAF 101/425 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AKAP7 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AL445989.1 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated, low confidence (0.06); called by muse, mutect2
- AL645922.1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 85/605 reads (14%) | called by muse, mutect2, varscan2
- ALG1 | c.1049C>A p.A350D | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AMBN | c.1332C>G p.F444L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ANK1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKIB1 | c.3019G>T p.G1007W | Missense Mutation (SNP) | VAF 277/498 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ANKRD30A | c.436G>A p.A146T (on ENST00000611781; = p.A90T on NM_052997.2) | Missense Mutation (SNP) | VAF 60/472 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD30A | c.1708-1G>T p.X570_splice (on ENST00000611781; = p.X514_splice on NM_052997.2) | Splice Site (SNP) | VAF 24/237 reads (10%) | called by muse, mutect2, varscan2
- ANKRD63 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.36); called by muse, mutect2, varscan2
- ANXA8 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 138/823 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP4B1 | c.618-5G>T | Splice Region (SNP) | VAF 58/239 reads (24%) | called by muse, mutect2, varscan2
- AP5M1 | c.1107G>T p.L369F | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- APP | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 114/974 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP23 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ARHGAP23 | c.3361G>T p.E1121* | Nonsense Mutation (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- ASB15 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 105/426 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, varscan2
- ASXL3 | c.5698C>A p.L1900M | Missense Mutation (SNP) | VAF 136/484 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.726); called by muse, varscan2
- ATAD3A | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 110/456 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP1B4 | c.889C>A p.P297T (on ENST00000218008 / NM_001142447.3; = p.P293T on NM_012069.5) | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP4B | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATR | c.3139G>C p.D1047H | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- BATF2 | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- BDKRB1 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 71/338 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BFSP2 | c.365T>A p.V122E | Missense Mutation (SNP) | VAF 126/855 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4759G>T p.V1587L | Missense Mutation (SNP) | VAF 61/437 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BNC2 | c.1769C>A p.P590Q | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- BNC2 | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 80/432 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- BOD1L1 | c.1533del p.N511Kfs*31 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- BPI | c.1285G>C p.V429L (on ENST00000262865; = p.V425L on NM_001725.3) | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2
- BUB1B | c.1344G>C p.E448D | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- C12orf40 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- C12orf42 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2
- C12orf50 | c.748G>T p.V250L | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CA1 | c.250C>G p.P84A | Missense Mutation (SNP) | VAF 162/858 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA2D3 | c.1921G>T p.D641Y | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CACNG6 | c.616G>A p.E206K (on ENST00000252729 / NM_145814.1; = p.E135K on NM_031897.2) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CADPS2 | c.2626G>T p.A876S | Missense Mutation (SNP) | VAF 66/499 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CALCRL | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- CALU | c.562A>T p.M188L | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CARMIL2 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CCDC18 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC40 | c.2668A>T p.S890C | Missense Mutation (SNP) | VAF 98/646 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC73 | c.3188C>A p.P1063Q | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- CCDC74B | c.1083del p.E362Rfs*53 | Frame Shift Del (DEL) | VAF 34/234 reads (15%) | called by mutect2, varscan2
- CCDC88C | c.2156C>T p.T719I | Missense Mutation (SNP) | VAF 172/706 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- CCDC93 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 104/435 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCM2 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CCT8L2 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 129/551 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.068); called by muse, varscan2
- CD300C | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- CD8A | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CDH15 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CDH4 | c.465G>T p.W155C | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH7 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2
- CDHR3 | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 55/524 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- CDK14 | c.56T>A p.L19* | Nonsense Mutation (SNP) | VAF 48/512 reads (9%) | called by muse, mutect2
- CDK5RAP3 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 101/538 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CDK9 | c.1035G>T p.K345N | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDON | c.3569G>C p.C1190S | Missense Mutation (SNP) | VAF 78/898 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2
- CENPT | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2
- CERCAM | c.1322G>T p.W441L | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CFAP43 | c.2216T>A p.M739K | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CFAP47 | c.2810A>C p.Q937P | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CFAP54 | c.8721G>T p.K2907N | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CFAP61 | c.842G>T p.S281I | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- CHD6 | c.7208G>T p.G2403V | Missense Mutation (SNP) | VAF 90/514 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CHD9 | c.2610G>T p.W870C | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHKB | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CHN1 | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 62/454 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRNB4 | c.54C>G p.R18= | Splice Region (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- CHST11 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CHST9 | c.1195C>A p.H399N | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.326); called by muse, mutect2
- CLEC4M | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CLSTN3 | c.1752G>T p.E584D | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CNGA3 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 105/1123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL11A1 | c.3880G>A p.G1294S | Missense Mutation (SNP) | VAF 193/777 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL11A2 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 48/650 reads (7%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.624); called by muse, mutect2
- COL12A1 | c.5024G>C p.W1675S | Missense Mutation (SNP) | VAF 106/473 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL19A1 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- COL3A1 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 136/758 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A1 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 115/811 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CPA2 | c.884G>C p.S295T | Missense Mutation (SNP) | VAF 129/478 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CR2 | c.543C>G p.Y181* | Nonsense Mutation (SNP) | VAF 103/1146 reads (9%) | called by muse, mutect2
- CRACD | c.2570G>C p.R857P | Missense Mutation (SNP) | VAF 118/602 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREBZF | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 84/322 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CRYBG3 | c.3459G>C p.E1153D | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CSF2RB | c.1794C>A p.H598Q | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CSHL1 | c.316C>G p.L106V (on ENST00000309894 / NM_022581.3; = p.L12V on NM_001318.4) | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD2 | c.7057G>T p.V2353L | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.133); called by muse, varscan2
- CSMD3 | c.9575G>T p.G3192V (on ENST00000297405 / NM_001363185.1; = p.G3023V on NM_052900.3) | Missense Mutation (SNP) | VAF 109/622 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CSMD3 | c.2482+1G>T p.X828_splice (on ENST00000297405 / NM_001363185.1; = p.X724_splice on NM_052900.3) | Splice Site (SNP) | VAF 30/284 reads (11%) | called by muse, varscan2
- CSMD3 | c.2395C>A p.H799N (on ENST00000297405 / NM_001363185.1; = p.H695N on NM_052900.3) | Missense Mutation (SNP) | VAF 69/338 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); called by muse, varscan2
- CSMD3 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 77/391 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- CSPG4 | c.1452C>A p.D484E | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CTNNA3 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTNNBL1 | c.853G>T p.G285* | Nonsense Mutation (SNP) | VAF 108/681 reads (16%) | called by muse, mutect2, varscan2
- CTNND1 | c.2354T>C p.V785A (on ENST00000399050 / NM_001085458.2; = p.V779A on NM_001331.3) | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CTSZ | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTXN2 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 77/498 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUBN | c.1957G>T p.G653C | Missense Mutation (SNP) | VAF 117/547 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4B1 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 83/384 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CYP4F2 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYRIA | c.131A>T p.D44V | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.371); called by muse, mutect2
- DAB2 | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 168/806 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- DACH1 | c.1607G>T p.G536V (on ENST00000619232 / NM_001366712.1; = p.G484V on NM_080759.6) | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- DBF4 | c.1271G>T p.R424I | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- DBX2 | c.257G>T p.C86F | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DCC | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 90/1106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCDC1 | c.3545T>C p.L1182P (on ENST00000597505 / NM_001367979.1; = p.L289P on NM_020869.3) | Missense Mutation (SNP) | VAF 308/1235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX54 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDX60L | c.4486G>T p.V1496L | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, varscan2
- DDX60L | c.3270G>C p.M1090I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DEFA3 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 48/1090 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- DENR | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGKI | c.157A>T p.M53L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- DGKK | c.1255T>A p.C419S | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIP2C | c.1368G>T p.E456D | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DLG1 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, varscan2
- DLK1 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DMD | c.7875G>T p.Q2625H | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DMD | c.2339C>A p.A780D | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DMRTA2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- DNAAF2 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH7 | c.6117+1G>A p.X2039_splice | Splice Site (SNP) | VAF 29/215 reads (13%) | called by muse, mutect2, varscan2
- DNAH7 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DNAH8 | c.5278G>T p.V1760L | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- DNAH9 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- DNAH9 | c.2537T>A p.M846K | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.7897C>A p.Q2633K | Missense Mutation (SNP) | VAF 141/980 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.371); called by muse, varscan2
- DNAH9 | c.8020C>A p.H2674N | Missense Mutation (SNP) | VAF 101/780 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, varscan2
- DNHD1 | c.11935C>A p.P3979T | Missense Mutation (SNP) | VAF 133/518 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNM1L | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 61/428 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DOCK4 | c.2473+4G>C | Splice Region (SNP) | VAF 178/728 reads (24%) | called by muse, mutect2, varscan2
- DOCK6 | c.2684T>A p.V895E | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- DOCK8 | c.2150G>C p.G717A | Missense Mutation (SNP) | VAF 130/623 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DSC3 | c.2288T>G p.F763C | Missense Mutation (SNP) | VAF 36/900 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- DSG3 | c.1456C>A p.P486T | Missense Mutation (SNP) | VAF 151/527 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- DSP | c.8416G>T p.A2806S | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DTNA | c.1423C>A p.L475M | Missense Mutation (SNP) | VAF 363/1151 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DTX1 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DUOX2 | c.3731C>A p.P1244H | Missense Mutation (SNP) | VAF 100/721 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYNC1H1 | c.13346G>C p.R4449P | Missense Mutation (SNP) | VAF 57/619 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNC1H1 | c.13663G>T p.A4555S | Missense Mutation (SNP) | VAF 105/541 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DYNC2I1 | c.2506del p.V836Sfs*8 | Frame Shift Del (DEL) | VAF 106/484 reads (22%) | called by mutect2, pindel, varscan2
- DZIP1 | c.531C>A p.C177* | Nonsense Mutation (SNP) | VAF 40/201 reads (20%) | called by muse, mutect2, varscan2
- E2F7 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EHF | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 37/251 reads (15%) | called by muse, mutect2, varscan2
- EIF5B | c.648T>G p.N216K | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELK4 | c.958A>T p.K320* | Nonsense Mutation (SNP) | VAF 119/516 reads (23%) | called by muse, mutect2, varscan2
- EN2 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2
- EPHB1 | c.1455G>T p.R485S | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERICH3 | c.1277A>T p.K426M | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- EXOC3L1 | c.2037C>A p.D679E | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EZH2 | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM13A | c.2173A>T p.K725* | Nonsense Mutation (SNP) | VAF 50/324 reads (15%) | called by muse, mutect2, varscan2
- FAM155A | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 125/960 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM171B | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 89/478 reads (19%) | called by muse, mutect2, varscan2
- FAM205A | c.1985C>G p.S662C | Missense Mutation (SNP) | VAF 68/562 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); called by muse, mutect2
- FAM71D | c.416T>A p.L139Q | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAM83C | c.1948G>T p.G650W | Missense Mutation (SNP) | VAF 115/487 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- FAM83C | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 128/447 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83F | c.711G>T p.R237S | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FAT2 | c.7705T>A p.C2569S | Missense Mutation (SNP) | VAF 134/805 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCHO1 | c.2029A>G p.S677G | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCHSD2 | c.579A>G p.L193= | Splice Region (SNP) | VAF 76/309 reads (25%) | called by muse, mutect2, varscan2
- FGD4 | c.1762G>T p.V588L | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGD5 | c.1973C>A p.A658E | Missense Mutation (SNP) | VAF 136/479 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FGFR1 | c.548C>A p.T183N (on ENST00000447712 / NM_023110.3; = p.T181N on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/511 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FGG | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 76/610 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- FIP1L1 | c.68A>G p.E23G | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FKBP1B | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG2 | c.3660G>T p.Q1220H | Missense Mutation (SNP) | VAF 62/554 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, varscan2
- FLNC | c.6945_6947delinsG p.H2315Qfs*40 | Frame Shift Del (DEL) | VAF 29/210 reads (14%) | called by pindel, varscan2*
- FLT1 | c.2153T>G p.I718S | Missense Mutation (SNP) | VAF 132/941 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- FMO3 | c.1171del p.Q391Kfs*2 | Frame Shift Del (DEL) | VAF 104/613 reads (17%) | called by mutect2, pindel, varscan2
- FOXD4 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 54/822 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- FOXL1 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 107/677 reads (16%) | called by muse, mutect2, varscan2
- FRG2C | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 98/1376 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- FSIP2 | c.15779C>A p.A5260D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- FUT1 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); called by muse, mutect2
- FYTTD1 | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FZD10 | c.1463A>C p.K488T | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- G6PC | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 149/1002 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA1 | c.1355C>A p.P452H | Missense Mutation (SNP) | VAF 115/776 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GABRA2 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRG2 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 68/392 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- GABRG3 | c.1108C>A p.L370I | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.122); called by muse, mutect2
- GAL3ST3 | c.394T>G p.F132V | Missense Mutation (SNP) | VAF 86/339 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- GALNT5 | c.195A>C p.K65N | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT6 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 93/555 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GATA4 | c.495C>A p.Y165* | Nonsense Mutation (SNP) | VAF 25/205 reads (12%) | called by muse, mutect2, varscan2
- GCM1 | c.838C>T p.L280F | Missense Mutation (SNP) | VAF 136/463 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GDAP2 | c.1204G>C p.D402H | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- GFRA1 | c.1176G>C p.L392F | Missense Mutation (SNP) | VAF 40/1054 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.122); called by muse, mutect2
- GHR | c.1336C>G p.P446A | Missense Mutation (SNP) | VAF 158/1043 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GIGYF1 | c.35+1G>T p.X12_splice | Splice Site (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- GIMAP8 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.066); called by muse, mutect2
- GLIS1 | c.592dup p.R198Pfs*10 | Frame Shift Ins (INS) | VAF 71/345 reads (21%) | called by mutect2, pindel, varscan2
- GLS | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GOLGB1 | c.9162+1G>T p.X3054_splice | Splice Site (SNP) | VAF 59/217 reads (27%) | called by muse, mutect2, varscan2
- GOLT1A | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR132 | c.10A>T p.M4L | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR137 | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.285); called by muse, mutect2
- GPR137B | c.959A>T p.K320M | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- GPR158 | c.1829C>A p.P610H | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR87 | c.1002G>T p.R334S | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- GRAMD1A | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 96/385 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GRAP2 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 84/328 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GRIN2B | c.995C>A p.S332Y | Missense Mutation (SNP) | VAF 67/777 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2
- GTPBP4 | c.1675G>T p.A559S | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, varscan2
- GUCA2B | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.284); called by muse, mutect2
- GUCY2D | c.2297T>A p.L766Q | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HAUS6 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HDAC5 | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | called by muse, varscan2
- HDHD5 | c.1105A>T p.R369W (on ENST00000336737 / NM_033070.3; = p.R339W on NM_017829.5) | Missense Mutation (SNP) | VAF 136/505 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- HEATR5B | c.5425C>G p.L1809V | Missense Mutation (SNP) | VAF 25/725 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); called by muse, mutect2
- HHLA1 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 108/694 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, varscan2
- HK2 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 91/612 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- HMCN2 | c.14207G>T p.G4736V | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- HNRNPLL | c.1525G>C p.A509P | Missense Mutation (SNP) | VAF 73/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- HOXA2 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 317/1299 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXA5 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HOXD12 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 72/466 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HTR3B | c.1215G>A p.W405* | Nonsense Mutation (SNP) | VAF 257/704 reads (37%) | called by muse, mutect2, varscan2
- IDE | c.851C>A p.P284Q | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- IGHA1 | c.410T>A p.L137Q | Missense Mutation (SNP) | VAF 129/575 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHMBP2 | c.2638G>C p.E880Q | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IGHV1-24 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 90/798 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGHV4-28 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 125/768 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- IGHV4-39 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 194/826 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- IGKV3-15 | c.50-1G>T p.X17_splice | Splice Site (SNP) | VAF 88/644 reads (14%) | called by muse, mutect2, varscan2
- IGLV1-40 | c.350G>C p.S117T | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IL12RB1 | c.1548C>A p.Y516* | Nonsense Mutation (SNP) | VAF 73/277 reads (26%) | called by muse, mutect2, varscan2
- IL18RAP | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- IL6 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- INPP5F | c.1549G>C p.A517P | Missense Mutation (SNP) | VAF 74/348 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- INSYN2B | c.986G>A p.C329Y | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQSEC3 | c.2398C>A p.P800T (on ENST00000538872 / NM_001170738.2; = p.P497T on NM_015232.1) | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ISM1 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 83/407 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA1 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 104/415 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ITGA1 | c.3078G>T p.E1026D | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA9 | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 154/467 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITPRID2 | c.701A>T p.Y234F | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- JAKMIP1 | c.1653G>T p.K551N | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- KATNIP | c.3493G>T p.A1165S | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2
- KCNIP4 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ12 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNQ2 | c.1346G>T p.G449V (on ENST00000359125 / NM_172107.4; = p.G421V on NM_004518.6) | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- KCTD16 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.114); called by muse, mutect2
- KDM5C | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 200/449 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KEL | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- KIAA0895 | c.958G>T p.A320S (on ENST00000297063 / NM_001100425.2; = p.A269S on NM_015314.3) | Missense Mutation (SNP) | VAF 104/449 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KIAA1755 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 102/497 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- KIAA2012 | c.1743G>T p.E581D | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- KIF21A | c.2929G>T p.E977* (on ENST00000361418 / NM_001378440.1; = p.E964* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 74/260 reads (28%) | called by muse, mutect2, varscan2
- KIFAP3 | c.711G>A p.W237* | Nonsense Mutation (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- KL | c.2918G>C p.C973S | Missense Mutation (SNP) | VAF 77/600 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHDC1 | c.982-45_982del p.X328_splice | Splice Site (DEL) | VAF 17/105 reads (16%) | called by mutect2, pindel
- KMT2B | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT3 | c.1231C>A p.L411I | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KRT33B | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT37 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KRT6C | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 137/1112 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- KRTAP23-1 | c.197A>T p.*66Lext*? | Nonstop Mutation (SNP) | VAF 63/411 reads (15%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.145del p.A49Pfs*75 (on ENST00000418998 / NM_001377303.1; = p.A27Pfs*75 on NM_032107.5) | Frame Shift Del (DEL) | VAF 40/346 reads (12%) | called by mutect2, varscan2
- L3MBTL3 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 26/231 reads (11%) | called by muse, mutect2, varscan2
- L3MBTL3 | c.2229G>T p.M743I | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, varscan2
- L3MBTL4 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 20/299 reads (7%) | called by muse, mutect2
- LAMA4 | c.3599G>T p.G1200V (on ENST00000230538 / NM_001105206.3; = p.G1193V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 266/981 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA4 | c.2257G>T p.A753S (on ENST00000230538 / NM_001105206.3; = p.A746S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 230/709 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMC3 | c.3437C>A p.P1146H | Missense Mutation (SNP) | VAF 129/712 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- LARS1 | c.999T>G p.N333K (on ENST00000394434 / NM_020117.11; = p.N306K on NM_016460.3) | Missense Mutation (SNP) | VAF 172/753 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- LDLRAP1 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 166/744 reads (22%) | called by muse, varscan2
- LLGL1 | c.591del p.V198Wfs*81 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- LPAR4 | c.890T>A p.L297* | Nonsense Mutation (SNP) | VAF 73/289 reads (25%) | called by muse, mutect2, varscan2
- LPXN | c.1110G>C p.Q370H | Missense Mutation (SNP) | VAF 59/493 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LRFN1 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRMDA | c.186G>C p.L62F | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- LRP1B | c.2983G>T p.D995Y | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC71 | c.1645C>A p.L549I | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRN1 | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- LSM1 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LYN | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 57/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYPD6 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.047); called by muse, mutect2
- MADD | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 51/426 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- MADD | c.1790G>C p.S597T | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEA3 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEB3 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEB6B | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAGEB6B | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 73/328 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MAGEL2 | c.3021G>C p.Q1007H | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MAGI1 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 116/438 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- MAML1 | c.2857dup p.A953Gfs*23 | Frame Shift Ins (INS) | VAF 32/166 reads (19%) | called by mutect2, pindel, varscan2
- MAP4K3 | c.155-2A>T p.X52_splice | Splice Site (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- MAST3 | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MATN1 | c.1035G>T p.M345I | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MBD2 | c.447G>T p.R149S | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- MBD3L1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 132/389 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCL1 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- MDH1B | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 23/306 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2
- MEIS1 | c.1126G>T p.G376* | Nonsense Mutation (SNP) | VAF 32/392 reads (8%) | called by muse, mutect2
- MEIS1 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2
- MGAM | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MGAT3 | c.1208T>G p.L403R | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MIA2 | c.1007C>A p.P336Q | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MIA3 | c.2234A>G p.K745R | Missense Mutation (SNP) | VAF 19/501 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- MLH3 | c.262A>T p.R88W | Missense Mutation (SNP) | VAF 78/663 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MME | c.1963C>A p.L655I | Missense Mutation (SNP) | VAF 76/499 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MOCS1 | c.1891G>T p.G631W | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOG | c.730+4A>T | Splice Region (SNP) | VAF 88/619 reads (14%) | called by muse, mutect2, varscan2
- MOGAT3 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 76/651 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MRC1 | c.407G>T p.W136L | Missense Mutation (SNP) | VAF 202/1161 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRGPRG | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.489); called by muse, mutect2
- MROH2B | c.2624C>T p.T875I | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- MRPL50 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 167/438 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- MTCL1 | c.3198G>T p.E1066D (on ENST00000306329 / NM_001378206.1; = p.E747D on NM_015210.4) | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); called by muse, mutect2
- MUC12 | c.2402C>G p.S801C (on ENST00000379442; = p.S658C on NM_001164462.1) | Missense Mutation (SNP) | VAF 1428/4945 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MUC16 | c.30194G>T p.S10065I | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- MUC19 | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MUC5B | c.14792C>A p.P4931H | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- MXRA5 | c.6113T>C p.I2038T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MYH11 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MYH2 | c.5272G>A p.E1758K | Missense Mutation (SNP) | VAF 263/1086 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- MYO15A | c.6056T>A p.L2019Q | Missense Mutation (SNP) | VAF 165/602 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO1E | c.1658A>T p.D553V | Missense Mutation (SNP) | VAF 127/903 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MYO5A | c.3052del p.Q1018Kfs*10 | Frame Shift Del (DEL) | VAF 100/747 reads (13%) | called by mutect2, pindel, varscan2
- MYPN | c.1192G>T p.V398L | Missense Mutation (SNP) | VAF 244/976 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NALCN | c.5122G>A p.D1708N | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBAS | c.1721A>T p.Y574F | Missense Mutation (SNP) | VAF 147/813 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- NDST4 | c.784del p.L262Ffs*14 | Frame Shift Del (DEL) | VAF 72/565 reads (13%) | called by mutect2, pindel, varscan2
- NDUFAF2 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NEFM | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NEFM | c.1490A>T p.E497V | Missense Mutation (SNP) | VAF 271/764 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- NFASC | c.1846C>A p.P616T | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- NIBAN1 | c.2131G>T p.A711S | Missense Mutation (SNP) | VAF 91/511 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NID1 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.379); called by muse, mutect2
- NLRP12 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 232/747 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NLRP3 | c.2904C>A p.S968R | Missense Mutation (SNP) | VAF 210/792 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NLRP5 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP8 | c.2852C>A p.P951H | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NMS | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NPC1L1 | c.2155C>A p.L719I | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NR4A3 | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRXN3 | c.1774C>G p.L592V (on ENST00000335750 / NM_001330195.2; = p.L219V on NM_004796.6) | Missense Mutation (SNP) | VAF 153/839 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NSG1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NTRK3 | c.1553G>T p.R518L | Missense Mutation (SNP) | VAF 103/645 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- NUP210L | c.4757G>T p.G1586V | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NUP58 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 77/564 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NUTM1 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 70/441 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NXPE3 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 176/792 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- OBSCN | c.14579G>T p.G4860V | Missense Mutation (SNP) | VAF 151/625 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OGFR | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- OR10G8 | c.504T>G p.C168W | Missense Mutation (SNP) | VAF 65/686 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10H3 | c.141G>T p.M47I | Missense Mutation (SNP) | VAF 121/453 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OR10S1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 61/337 reads (18%) | called by muse, mutect2, varscan2
- OR10T2 | c.520A>T p.R174W | Missense Mutation (SNP) | VAF 62/371 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- OR1N1 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OR2T6 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.029); called by muse, varscan2
- OR4D2 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 272/1616 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR52A5 | c.722T>A p.F241Y | Missense Mutation (SNP) | VAF 53/585 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- OR52A5 | c.721T>A p.F241I | Missense Mutation (SNP) | VAF 54/594 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2
- OR52E4 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- OR52L1 | c.815del p.P272Lfs*41 | Frame Shift Del (DEL) | VAF 69/630 reads (11%) | called by mutect2, pindel, varscan2
- OR52N5 | c.761T>A p.I254K | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- OR52N5 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 134/462 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52R1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 145/621 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- OR5T1 | c.182T>A p.I61N | Missense Mutation (SNP) | VAF 55/412 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- OR5T2 | c.215_216insT p.I73Nfs*18 | Frame Shift Ins (INS) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- OR5T3 | c.127T>C p.F43L | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- OR6K3 | c.558del p.N188Tfs*14 (on ENST00000368146; = p.N172Tfs*14 on NM_001005327.2) | Frame Shift Del (DEL) | VAF 148/786 reads (19%) | called by mutect2, pindel, varscan2
- OSBPL8 | c.2426G>T p.G809V | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OTOF | c.2091C>A p.D697E | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OTOGL | c.5630G>T p.G1877V (on ENST00000547103; = p.G1868V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/410 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OTUD4 | c.1073-1G>A p.X358_splice (on ENST00000447906 / NM_001366057.1; = p.X293_splice on NM_001102653.1) | Splice Site (SNP) | VAF 50/200 reads (25%) | called by muse, mutect2, varscan2
- OVCH1 | c.1714del p.S572Pfs*21 | Frame Shift Del (DEL) | VAF 60/304 reads (20%) | called by pindel, varscan2
- OVCH1 | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 118/418 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.358); called by muse, mutect2
- PAPPA2 | c.3791G>C p.W1264S | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PAX1 | c.1472C>A p.A491E | Missense Mutation (SNP) | VAF 56/321 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDH10 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDH11X | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 60/372 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH15 | c.1665C>A p.D555E | Missense Mutation (SNP) | VAF 211/1144 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- PCDH8 | c.1837G>T p.A613S | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, varscan2
- PCDH8 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCDHGA7 | c.974C>A p.P325H | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PDGFRB | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.034); called by muse, varscan2
- PDRG1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, varscan2
- PERM1 | c.1636G>T p.V546F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- PHACTR1 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PIK3C2G | c.1330G>T p.V444L | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2
- PIK3CD | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PIWIL1 | c.2036T>C p.L679P | Missense Mutation (SNP) | VAF 84/397 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PKHD1 | c.5095C>T p.H1699Y | Missense Mutation (SNP) | VAF 94/1202 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2
- PKHD1 | c.1370A>T p.E457V | Missense Mutation (SNP) | VAF 59/895 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.025); called by muse, mutect2
- PLA2G4F | c.2493G>T p.K831N | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PNLIPRP1 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 87/372 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- POLA1 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 89/339 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- POLDIP3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 62/506 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- POLDIP3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 59/498 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- POLR3B | c.3319C>G p.P1107A | Missense Mutation (SNP) | VAF 119/885 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEC | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 303/1319 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POU6F2 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PPDPFL | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2
- PPP1R1C | c.168C>A p.N56K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2
- PRAMEF15 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 160/1275 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, varscan2
- PRIM1 | c.485G>T p.R162M | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRR23C | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- PRRC2C | c.1695A>T p.K565N (on ENST00000367742; = p.K563N on NM_015172.4) | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PSD2 | c.750T>A p.D250E | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PSD2 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- PSKH2 | c.317T>A p.V106E | Missense Mutation (SNP) | VAF 136/869 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMA8 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCHD4 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 16/438 reads (4%) | called by muse, mutect2
- PTCHD4 | c.1037T>A p.L346Q | Missense Mutation (SNP) | VAF 204/778 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PTGDR | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 140/621 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- PTK2 | c.2638G>T p.G880* | Nonsense Mutation (SNP) | VAF 61/559 reads (11%) | called by muse, mutect2, varscan2
- PTK2B | c.2148G>A p.K716= | Splice Region (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- PTPRD | c.1741T>C p.Y581H | Missense Mutation (SNP) | VAF 138/571 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PTPRQ | c.1463C>A p.T488N (on ENST00000616559; = p.T446N on NM_001145026.2) | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PTPRZ1 | c.887T>A p.V296E | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDNL | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 81/437 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- R3HDM1 | c.2201A>T p.Q734L | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RAB5IF | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- RAD54L2 | c.1029G>C p.W343C | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPB | c.194G>T p.W65L | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RANBP3L | c.1205T>A p.I402K | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRP4 | c.1013G>C p.R338P | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBBP4 | c.999A>C p.L333F | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- RBFA | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, varscan2
- REG3A | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 38/389 reads (10%) | called by muse, mutect2
- REN | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 185/668 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
598 further variants in this file (192 protein-altering or splice-affecting, 258 silent, 148 other) are not listed here.
